Gene-level copy-number profile of tumor specimen TCGA-BA-A6DD-01A from TCGA case TCGA-BA-A6DD, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 44.9 years (16,401 days).
Specimen TCGA-BA-A6DD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.450b3fdb-d489-404b-9131-dfa3d4626b53.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-A6DD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/685c2a0b-7b74-4567-9877-84bce2af4fdb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 9,637; copy number 2: 42,908; copy number 3: 2,445; copy number 4: 4,466; copy number 5: 240; copy number 6: 66; copy number 12: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-A6DD-01A-12D-A31K-01): tumor purity 0.21, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:70,430,231–71,208,366, 8 genes (within-gene range 0–2): RPS2P6, AC091305.1, AC091646.1, RN7SL795P, GTSCR1, AC090415.2, AC090415.1, AC091691.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 350 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:6,770,001–7,741,533, 1 gene, copy number 5 (within-gene range 4–5): GRM7.
- chr3:6,892,632–9,398,579, 27 genes, copy number 5 (within-gene range 3–5): GRM7-AS2, AC066585.1, GRM7-AS1, AC077690.1, LMCD1-AS1, AC018832.1, AC023481.1, RNU4ATAC17P, LMCD1, AC034187.1, SSUH2, OR7E122P, CAV3, OXTR, RAD18, AC034186.2, AC034186.1, SRGAP3, SRGAP3-AS1, AC037193.1, SRGAP3-AS2, SRGAP3-AS3, SRGAP3-AS4, AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3.
- chr3:164,978,898–167,825,569, 29 genes, copy number 5 (within-gene range 4–5): SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1.
- chr3:187,120,948–193,378,820, 71 genes, copy number 5 (broad region; genes not listed).
- chr8:63,013,068–69,660,915, 98 genes, copy number 5 (broad region; genes not listed).
- chr8:69,700,224–69,700,495, 1 gene, copy number 5: RN7SKP29.
- chr8:117,794,490–119,325,265, 13 genes, copy number 5: EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ.
- chr11:32,112,049–35,232,402, 66 genes, copy number 6 (broad region; genes not listed).
- chr11:69,371,463–71,252,577, 44 genes, copy number 12: AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.

Autosomal genes at a single copy (total copy number 1): 7,251. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
